Somatic mutation profile of tumor specimen C3N-00167-02 (aliquot CPT0013600009) from CPTAC case C3N-00167, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,543 days).
Specimen C3N-00167-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 147c9fd3-60c8-4e1f-a3de-0e74370f1f65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00167-31 (Blood Derived Normal), aliquot CPT0016510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea194c8f-ab0b-40ae-a263-52573942444f

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Nonsense Mutation 3, Splice Site 1, In Frame Del 1, Frame Shift Del 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 191/552 reads (35%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 111/331 reads (34%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV55844091; called by muse, mutect2, varscan2
- BRSK1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs771561869, COSV58667443; called by muse, mutect2, varscan2
- CFAP46 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770651215, COSV100886526; called by muse, mutect2, varscan2
- DNAH9 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1357212853, COSV52379605; called by muse, mutect2, varscan2
- EHBP1L1 | c.1329_1330del p.V445Dfs*3 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | catalogued as rs754919584; called by mutect2, pindel, varscan2
- ERICH6 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs756822036; called by muse, mutect2, varscan2
- FOXA3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as COSV56216300; called by muse, mutect2, varscan2
- GABRB2 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs150956270, COSV50906276; called by muse, mutect2, varscan2
- HSD17B4 | c.2275G>A p.A759T (on ENST00000414835 / NM_001199291.3; = p.A734T on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs751064948, COSV56336974; called by muse, mutect2, varscan2
- KLHL1 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1016616139; called by muse, mutect2, varscan2
- MEIS1 | c.1098G>T p.M366I | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV104378938; called by muse, mutect2, varscan2
- NKX2-3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV60728929; called by muse, mutect2
- OBSCN | c.10825G>A p.V3609M | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as rs374049885, COSV52789522; called by muse, mutect2, varscan2
- PARP14 | c.2411T>C p.L804P | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758216826; called by muse, mutect2, varscan2
- PCDHB6 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 61/577 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV50718092; called by muse, mutect2, varscan2
- PLD1 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577465; called by muse, mutect2
- TENT4A | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50095729; called by muse, mutect2, varscan2
- AMER3 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANKMY2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 64/225 reads (28%) | called by muse, varscan2
- ASB3 | c.-13-21_-2del | Splice Site (DEL) | VAF 18/172 reads (10%) | called by mutect2, pindel
- CAMSAP2 | c.1964C>T p.S655F (on ENST00000236925 / NM_001297707.2; = p.S644F on NM_203459.3) | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CNR2 | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTX4 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT4 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); called by muse, mutect2
- FRMD6 | c.982C>A p.Q328K (on ENST00000344768 / NM_001267046.2; = p.Q320K on NM_152330.4) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- GRIN2A | c.1007+4A>C | Splice Region (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2
- KRT71 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2
- PHF21A | c.694C>T p.P232S (on ENST00000418153 / NM_001101802.3; = p.P233S on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PPME1 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R12B | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 33/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPS1L1 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 30/753 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2
- SRCIN1 | c.1315G>A p.E439K (on ENST00000621492; = p.E405K on NM_025248.3) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TET2 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM223 | c.561_564dup p.T189* | Nonsense Mutation (INS) | VAF 28/147 reads (19%) | called by mutect2, pindel, varscan2
- TNFRSF21 | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP11A | c.2775G>A p.S925= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs766546330, COSV100276627; called by muse, mutect2, varscan2
- DUOXA1 | c.690C>T p.L230= | Silent (SNP) | VAF 23/469 reads (5%) | catalogued as COSV50993074; called by muse, mutect2
- EPG5 | c.1221G>T p.L407= | Silent (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- FKBP8 | c.306G>A p.L102= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs1218649854; called by muse, mutect2, varscan2
- GLDC | c.1572G>C p.V524= | Silent (SNP) | VAF 62/272 reads (23%) | called by muse, mutect2, varscan2
- PSMB2 | c.435A>G p.R145= | Silent (SNP) | VAF 11/76 reads (14%) | called by mutect2, varscan2
- RTN1 | c.1176G>A p.P392= | Silent (SNP) | VAF 47/216 reads (22%) | catalogued as rs944737200, COSV50723951; called by muse, mutect2, varscan2
- SLITRK2 | c.1152G>C p.G384= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as rs782146802, COSV59428898; called by muse, mutect2, varscan2
- ZNF580 | c.129G>C p.A43= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- SLC9A8 | c.*26G>A | 3'UTR (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
